Somatic mutation profile of tumor specimen TCGA-A2-A25E-01A (aliquot TCGA-A2-A25E-01A-11D-A167-09) from TCGA case TCGA-A2-A25E, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 34.5 years (12,601 days).
Specimen TCGA-A2-A25E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24c2e723-5d7b-448a-84a5-c1fafe71cd40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A25E-10A (Blood Derived Normal), aliquot TCGA-A2-A25E-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96fe0824-d80f-4e3a-826f-ea68bfc26b70

The open-access MAF lists 62 somatic variants for this specimen: 52 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 9, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 2, Splice Site 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as rs1232958056, COSV52221202; called by muse, mutect2, varscan2
- ARHGAP18 | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100936002; called by muse, mutect2, varscan2
- ATP1A4 | c.983C>G p.A328G | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV63626309, COSV63626743; called by muse, mutect2, varscan2
- ATP9A | c.2092C>A p.Q698K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV58765799; called by muse, mutect2, varscan2
- ATXN1 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV55214699; called by muse, mutect2, varscan2
- AWAT2 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV52143220; called by muse, mutect2, varscan2
- BSND | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs770850590, COSV100987600; called by muse, mutect2
- C5 | c.759A>T p.R253S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV56326516; called by muse, mutect2, varscan2
- CEP85 | c.799T>G p.W267G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53328975; called by muse, mutect2, varscan2
- CHPT1 | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV57533236; called by muse, mutect2, varscan2
- ENTPD7 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100978335; called by muse, mutect2, varscan2
- ERC1 | c.3016C>G p.P1006A (on ENST00000360905 / NM_178040.4; = p.P978A on NM_178039.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV100705739, COSV61694124; called by muse, mutect2, varscan2
- FIGLA | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs782634410, COSV60089021; called by muse, mutect2, varscan2
- GIMAP6 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV61033246; called by muse, mutect2, varscan2
- GLI2 | c.252C>G p.H84Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58040273, COSV58043522; called by muse, mutect2, varscan2
- GSK3A | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV55899026; called by muse, mutect2, varscan2
- H2AC13 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.18); catalogued as COSV62440727; called by muse, mutect2, varscan2
- H2BC6 | c.373_374insTGG p.S125delinsLA | In Frame Ins (INS) | VAF 7/23 reads (30%) | catalogued as COSV61591004; called by mutect2, pindel*, varscan2
- HPD | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV99999990; called by muse, mutect2
- IQGAP2 | c.3481C>T p.L1161F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV57170263; called by muse, mutect2, varscan2
- ITIH2 | c.1631T>C p.V544A | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV64432885; called by muse, mutect2, varscan2
- KIAA0319 | c.2703G>C p.L901F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65497963; called by muse, mutect2, varscan2
- LNX2 | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.222); catalogued as COSV60335411; called by muse, mutect2, varscan2
- LYST | c.9136A>G p.N3046D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.351); catalogued as COSV67706390; called by muse, mutect2, varscan2
- MAP3K13 | c.1010+1G>A p.X337_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53987815; called by muse, mutect2, varscan2
- MAP3K6 | c.3561C>G p.Y1187* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV58871409; called by muse, mutect2, varscan2
- MOGAT3 | c.386C>G p.T129S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV56174088; called by muse, mutect2, varscan2
- NEDD4L | c.1937C>A p.A646D (on ENST00000400345 / NM_001144967.3; = p.A626D on NM_015277.6) | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99893218; called by muse, mutect2
- NSFL1C | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.93); catalogued as COSV53793148; called by muse, mutect2, varscan2
- NTRK2 | c.1723A>T p.K575* (on ENST00000323115 / NM_001369534.1; = p.K591* on NM_006180.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52862156; called by muse, mutect2, varscan2
- PHKA2 | c.1715C>A p.T572K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.04); catalogued as COSV66053554; called by muse, mutect2, varscan2
- RBM46 | c.218A>T p.Y73F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.071); catalogued as COSV55978438; called by muse, mutect2, varscan2
- RHBDF2 | c.1600A>G p.M534V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51684384; called by muse, mutect2, varscan2
- RNASEK-C17orf49 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as COSV52349457; called by muse, mutect2, varscan2
- ROCK1 | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV67695708; called by muse, mutect2, varscan2
- SART3 | c.2168C>T p.T723I (on ENST00000228284; = p.T705I on NM_014706.4) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57206914; called by muse, mutect2, varscan2
- SLC16A1 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs151166713; called by muse, mutect2, varscan2
- TMEM86A | c.497G>C p.R166P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV55010552, COSV99773826; called by muse, mutect2, varscan2
- TNFSF4 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1232689355, COSV56055807; called by muse, mutect2, varscan2
- UGT2B7 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs138302870, COSV100535244; called by muse, mutect2, varscan2
- WDR33 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59248211; called by muse, mutect2, varscan2
- WWC3 | c.2687C>G p.S896W | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66502817; called by muse, mutect2, varscan2
- ZNF16 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52763435; called by muse, mutect2, varscan2
- ZNF546 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs1284824998, COSV61257748; called by muse, mutect2, varscan2
- CX3CR1 | c.1001_1005delinsTC p.H334_G335delinsL | In Frame Del (DEL) | VAF 15/27 reads (56%) | called by pindel, varscan2*
- KBTBD4 | c.98_111delinsAGGAGGAGCTCTT p.G33Efs*7 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by muse*, pindel
- KMT2A | c.2701_2703delinsTAAAACA p.S901* | Nonsense Mutation (INS) | VAF 24/45 reads (53%) | called by pindel, varscan2*
- NR2C1 | c.237_285del p.N80Sfs*2 | Frame Shift Del (DEL) | VAF 21/160 reads (13%) | called by mutect2, pindel
- RAD51AP1 | c.1003G>T p.G335C (on ENST00000228843 / NM_001130862.2; = p.G318C on NM_006479.5) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX12 | c.357_375del p.R119Sfs*? (on ENST00000622259; = p.R119Sfs*53 on NM_013346.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- TCTEX1D2 | c.52_57del p.A18_E19del | In Frame Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- WSB1 | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADGRF5 | c.366C>T p.C122= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs138073254; called by muse, mutect2, varscan2
- BRWD3 | c.789T>C p.H263= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV64747217; called by muse, mutect2, varscan2
- CCDC60 | c.1293G>A p.K431= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV59543079, COSV59551862; called by muse, mutect2, varscan2
- ITGAX | c.2412A>G p.E804= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV51645029; called by muse, mutect2, varscan2
- LIN9 | c.1369C>A p.R457= (on ENST00000366808 / NM_001270410.2; = p.R402= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV60244820, COSV60247046; called by muse, mutect2, varscan2
- SDK1 | c.891T>C p.V297= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs757398943, COSV101268711; called by muse, mutect2, varscan2
- SLC3A2 | c.1077C>T p.F359= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV58603306; called by muse, mutect2, varscan2
- TTC17 | c.408C>T p.S136= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV50005988; called by muse, mutect2, varscan2
- USP1 | c.99T>G p.T33= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV60574222; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840687 T>A | 5'Flank (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100005107; called by muse, mutect2
